Somatic mutation profile of tumor specimen TCGA-B8-5163-01A (aliquot TCGA-B8-5163-01A-01D-1421-08) from TCGA case TCGA-B8-5163, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.8 years (23,293 days).
Specimen TCGA-B8-5163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e547f343-c344-4b9a-9122-e8b887676c79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5163-10A (Blood Derived Normal), aliquot TCGA-B8-5163-10A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b1c99eb-6fff-4c6b-856c-f05fcb86ef43

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Frame Shift Del 6, In Frame Del 3, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 50/256 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD962176, CM056724, CM114396, COSV56542752, COSV56558534; called by muse, mutect2, varscan2
- ADAM10 | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53051009; called by muse, mutect2
- AGL | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV54051470; called by muse, mutect2, varscan2
- ALK | c.4056G>C p.K1352N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV66564812; called by muse, mutect2, varscan2
- ANKS1B | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61346196; called by muse, mutect2, varscan2
- ATAD5 | c.4635T>A p.N1545K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58973663; called by muse, mutect2, varscan2
- BIRC6 | c.2566A>G p.I856V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs768566974, COSV70198118; called by muse, mutect2, varscan2
- BRMS1L | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53762970, COSV53763391; called by muse, mutect2, varscan2
- C11orf24 | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.075); catalogued as COSV58505375; called by muse, mutect2, varscan2
- C4BPA | c.728A>C p.D243A | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.166); catalogued as rs1216728529, COSV65536205; called by muse, mutect2, varscan2
- CACNA1C | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 44/254 reads (17%) | catalogued as rs1555614891, COSV59710205; called by muse, varscan2
- CEACAM5 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV55751755; called by muse, mutect2, varscan2
- CFAP20DC | c.427A>T p.T143S (on ENST00000482387 / NM_001351530.2; = p.T18S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55918724; called by muse, mutect2, varscan2
- CHD1 | c.4153T>G p.S1385A | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52339416; called by muse, mutect2, varscan2
- CIB3 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV54165948; called by muse, mutect2
- COL24A1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV65304951; called by muse, mutect2
- DCT | c.930T>G p.N310K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV65468629; called by muse, mutect2, varscan2
- DNAH17 | c.7768T>A p.F2590I | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV67752519; called by muse, mutect2
- EZH2 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 69/558 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV57451131; called by muse, mutect2, varscan2
- FAM13C | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 147/464 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs745910965, COSV53246995; called by muse, mutect2, varscan2
- FBN2 | c.5391C>A p.F1797L | Missense Mutation (SNP) | VAF 50/363 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV52507476; called by muse, mutect2, varscan2
- GHR | c.1435A>C p.S479R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as COSV50107620; called by muse, mutect2, varscan2
- GPR137 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57401821; called by muse, mutect2, varscan2
- IRF2BP1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV56193324; called by muse, mutect2, varscan2
- KIF4A | c.1878G>C p.K626N | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65542693; called by muse, mutect2, varscan2
- KIFC2 | c.1412C>G p.S471C | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56760740; called by muse, mutect2, varscan2
- KRT28 | c.977C>A p.T326K | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV60684804; called by muse, mutect2, varscan2
- KRTAP4-1 | c.404C>G p.T135S (on ENST00000398472; = p.T116S on NM_033060.3) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.53); catalogued as rs1404830937, COSV66648191; called by muse, mutect2
- MEGF10 | c.1352del p.N451Tfs*47 | Frame Shift Del (DEL) | VAF 62/406 reads (15%) | catalogued as COSV57248068; called by pindel, varscan2*
- MTF1 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV65988805; called by muse, mutect2, varscan2
- MYO1E | c.2457A>T p.E819D | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV55685610; called by muse, mutect2, varscan2
- NCOA6 | c.2630A>T p.N877I | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV62862883; called by muse, varscan2
- NCOA6 | c.2590A>T p.N864Y | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV62862887; called by muse, varscan2
- PCDH7 | c.2758G>C p.E920Q | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV62338102; called by muse, mutect2, varscan2
- PGBD1 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV52552642; called by muse, mutect2, varscan2
- PIK3CB | c.1784T>C p.L595P | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV56685145; called by muse, mutect2, varscan2
- PPP1R21 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54283980; called by muse, mutect2, varscan2
- PRDM4 | c.727A>T p.N243Y | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV57305454; called by muse, mutect2, varscan2
- SRMS | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as COSV53920406; called by muse, mutect2, varscan2
- STARD3 | c.795+1G>A p.X265_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as COSV59223419; called by muse, mutect2
- STAT6 | c.1776C>A p.F592L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55666012; called by muse, mutect2, varscan2
- TARBP1 | c.2105G>A p.C702Y | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV50182609; called by muse, mutect2, varscan2
- TRAPPC12 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV60846866; called by muse, mutect2, varscan2
- TSNAXIP1 | c.493_495del p.E165del | In Frame Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs754888426; called by pindel, varscan2
- UBE2W | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as COSV62475252; called by muse, mutect2, varscan2
- UGT2B15 | c.1216C>A p.H406N | Missense Mutation (SNP) | VAF 66/528 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV57734082; called by muse, mutect2, varscan2
- USP36 | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61751249; called by muse, mutect2
- ZFP42 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs1471218939, COSV58817089; called by muse, mutect2, varscan2
- ZNF350 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV54708463; called by muse, mutect2
- AHNAK2 | c.14995del p.S4999Lfs*33 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel*, varscan2*
- DIP2B | c.2524dup p.Y842Lfs*2 | Frame Shift Ins (INS) | VAF 19/180 reads (11%) | called by mutect2, pindel
- FASTK | c.858del p.L287* | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- OTULIN | c.201del p.E67Dfs*14 | Frame Shift Del (DEL) | VAF 56/221 reads (25%) | called by mutect2, pindel, varscan2
- PCK1 | c.211_213del p.K71del | In Frame Del (DEL) | VAF 24/117 reads (21%) | called by pindel, varscan2
- TCIRG1 | c.2258_2263del p.A753_M754del | In Frame Del (DEL) | VAF 23/195 reads (12%) | called by mutect2, pindel, varscan2
- XG | c.67del p.R23Efs*118 | Frame Shift Del (DEL) | VAF 52/307 reads (17%) | called by mutect2, pindel, varscan2
- ZNF561 | c.576_585del p.A193Pfs*45 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel
- ACOT6 | c.231T>C p.T77= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as COSV66968916; called by muse, mutect2, varscan2
- AZI2 | c.732A>G p.L244= | Silent (SNP) | VAF 45/209 reads (22%) | catalogued as COSV55423712; called by muse, mutect2, varscan2
- CUL9 | c.777G>A p.L259= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV52727684; called by muse, mutect2, varscan2
- DCAF6 | c.1350A>G p.A450= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV56577613; called by muse, mutect2, varscan2
- DHTKD1 | c.1701C>A p.I567= | Silent (SNP) | VAF 98/341 reads (29%) | catalogued as COSV53802933; called by muse, mutect2, varscan2
- GLB1L2 | c.1206C>T p.Y402= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as COSV60278276; called by muse, mutect2, varscan2
- ITK | c.1074C>A p.I358= | Silent (SNP) | VAF 57/258 reads (22%) | catalogued as COSV70061829; called by muse, mutect2, varscan2
- KRBA2 | c.39A>C p.P13= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV58778957; called by muse, mutect2, varscan2
- NUDT15 | c.450A>G p.K150= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as COSV51642114; called by muse, mutect2, varscan2
- OTUD7B | c.1143T>C p.D381= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV64915895; called by muse, mutect2, varscan2
- PSEN1 | c.1392A>G p.Q464= | Silent (SNP) | VAF 76/419 reads (18%) | catalogued as COSV56194069; called by muse, mutect2, varscan2
- RBFA | c.273G>A p.A91= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as rs142434986; called by muse, mutect2, varscan2
- TCN1 | c.966T>C p.P322= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV57252924; called by muse, mutect2, varscan2
- ZNF418 | c.375T>A p.R125= | Silent (SNP) | VAF 42/278 reads (15%) | catalogued as COSV68675773; called by muse, mutect2, varscan2
- ZSCAN31 | c.649A>C p.R217= | Silent (SNP) | VAF 77/210 reads (37%) | catalogued as COSV60180694; called by muse, mutect2, varscan2
- TBC1D29P | n.2581T>C | RNA (SNP) | VAF 27/150 reads (18%) | catalogued as COSV73694578; called by muse, varscan2
